Somatic mutation profile of tumor specimen C3N-00150-02 (aliquot CPT0066490009) from CPTAC case C3N-00150, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.5 years (20,286 days).
Specimen C3N-00150-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68ed6489-a549-463e-9597-6f2e5ab6a94b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00150-31 (Blood Derived Normal), aliquot CPT0071650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c51d08b3-bd61-4110-94b7-adfadf8fbb2b

The open-access MAF lists 83 somatic variants for this specimen: 61 protein-altering or splice-affecting, 9 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 9, Frame Shift Del 6, Intron 5, Splice Site 4, 3'UTR 3, Frame Shift Ins 2, 5'Flank 2, 5'UTR 1, Nonsense Mutation 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4448G>T p.C1483F | Missense Mutation (SNP) | VAF 20/110 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs786205165, CM1412980, CM153079, COSV63869079, COSV63869516; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARAP2 | c.2683C>G p.L895V | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.699); catalogued as rs373281502; called by muse, mutect2, varscan2
- ARHGEF10 | c.2862A>C p.E954D (on ENST00000398564; = p.E929D on NM_014629.4) | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV50642244; called by muse, mutect2
- CEMIP | c.965-1G>C p.X322_splice | Splice Site (SNP) | VAF 55/383 reads (14%) | catalogued as rs769389649; called by muse, mutect2, varscan2
- CNN2 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.211); catalogued as rs141801176, COSV99565612; called by muse, mutect2, varscan2
- CTNNA1 | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.315); catalogued as rs758284033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHCR7 | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 73/390 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM034225; called by muse, mutect2, varscan2
- DMXL2 | c.3242G>A p.R1081H | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757597201; called by muse, mutect2, varscan2
- DNAJB5 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as rs1272825498; called by muse, mutect2, varscan2
- GK5 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 20/108 reads (19%) | catalogued as rs772711539, COSV101242336; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV57131444; called by muse, mutect2, varscan2
- OPCML | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100098179, COSV59418118; called by muse, mutect2
- RASGRP4 | c.1477C>G p.R493G | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV53039900, COSV99384963; called by muse, mutect2, varscan2
- SLC22A31 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs751321737; called by muse, varscan2
- TBX3 | c.1999G>A p.A667T (on ENST00000257566 / NM_016569.4; = p.A647T on NM_005996.4) | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1268167495; called by mutect2, varscan2
- TRIM38 | c.392A>T p.D131V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1182611170; called by muse, mutect2, varscan2
- TSR1 | c.337T>G p.L113V | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs750230871; called by muse, mutect2, varscan2
- ZDHHC11B | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.129); catalogued as COSV66978676; called by muse, varscan2
- ZDHHC11B | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1175348274; called by muse, mutect2, varscan2
- ZNF638 | c.3103G>T p.D1035Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV52485566; called by muse, mutect2, varscan2
- AACS | c.1881+1G>T p.X627_splice | Splice Site (SNP) | VAF 24/127 reads (19%) | called by muse, mutect2
- AKAP4 | c.1509G>T p.E503D | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ALOX12B | c.1224del p.F409Sfs*6 | Frame Shift Del (DEL) | VAF 28/228 reads (12%) | called by mutect2, pindel, varscan2
- ASPSCR1 | c.1348T>G p.F450V | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- BICDL2 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CASP8AP2 | c.3253_3254del p.L1085Tfs*5 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- CCDC153 | c.44A>T p.Q15L | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CDKN2D | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CERKL | c.1208A>C p.E403A (on ENST00000339098 / NM_001030311.2; = p.E377A on NM_201548.5) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CNN2 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPLANE1 | c.8423_8424del p.S2808Cfs*9 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- CUL9 | c.1682A>C p.N561T | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUL9 | c.4687G>T p.G1563C | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DROSHA | c.2995T>C p.Y999H | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- E2F2 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ELF3 | c.177G>C p.W59C | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ESF1 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBLN1 | c.1385A>G p.Q462R | Missense Mutation (SNP) | VAF 72/446 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FYCO1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GCGR | c.949-2A>G p.X317_splice | Splice Site (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2
- GRAMD1B | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GRB2 | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2A | c.9122_9125del p.I3041Rfs*30 | Frame Shift Del (DEL) | VAF 24/166 reads (14%) | called by mutect2, pindel, varscan2
- L3MBTL2 | c.1051_1052dup p.R352Vfs*24 | Frame Shift Ins (INS) | VAF 35/200 reads (18%) | called by mutect2, pindel, varscan2
- MAPK9 | c.512G>C p.G171A | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NAMPT | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLRX1 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPHP3 | c.3847T>A p.L1283I | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OVCH1 | c.2045C>A p.P682Q | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by mutect2, varscan2
- PRSS36 | c.1601G>T p.C534F | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB7A | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- RANBP9 | c.1722A>T p.E574D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RTKN | c.1195_1196del p.E399Kfs*18 (on ENST00000272430 / NM_001015055.2; = p.E386Kfs*18 on NM_033046.2) | Frame Shift Del (DEL) | VAF 21/170 reads (12%) | called by mutect2, pindel, varscan2
- SIRT1 | c.1840del p.T614Lfs*7 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | called by mutect2, varscan2
- SLC25A39 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SNAPC4 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SNCG | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TIAL1 | c.372-2A>G p.X124_splice | Splice Site (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- TMEM26 | c.471A>G p.I157M | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- UGT1A4 | c.354_355insGG p.N119Gfs*20 | Frame Shift Ins (INS) | VAF 42/247 reads (17%) | called by mutect2, pindel, varscan2
- ZIC3 | c.1387A>T p.N463Y | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AMPD3 | c.306C>T p.A102= (on ENST00000396553 / NM_001025389.2; = p.A111= on NM_000480.3) | Silent (SNP) | VAF 72/384 reads (19%) | called by muse, mutect2, varscan2
- CACNA1H | c.2658C>T p.F886= | Silent (SNP) | VAF 46/261 reads (18%) | catalogued as rs1202009471; called by muse, mutect2, varscan2
- CHD8 | c.3091A>C p.R1031= (on ENST00000646647 / NM_001170629.2; = p.R752= on NM_020920.4) | Silent (SNP) | VAF 35/184 reads (19%) | called by muse, mutect2, varscan2
- GRIN3A | c.744T>C p.S248= | Silent (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1209C>A p.T403= (on ENST00000485419 / NM_001197113.1; = p.T327= on NM_014575.3) | Silent (SNP) | VAF 31/153 reads (20%) | called by muse, mutect2, varscan2
- MUC12 | c.2709C>G p.T903= (on ENST00000379442; = p.T760= on NM_001164462.1) | Silent (SNP) | VAF 88/1794 reads (5%) | called by muse, mutect2
- NUP160 | c.1866A>T p.S622= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1476C>T p.L492= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV99693773; called by muse, mutect2, varscan2
- ZGRF1 | c.378A>T p.P126= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 17/33 reads (52%) | catalogued as rs190105354; called by muse, varscan2
- ANKRD26 | c.1635+2119C>T | Intron (SNP) | VAF 29/182 reads (16%) | catalogued as rs1213133783; called by muse, mutect2, varscan2
- BTN3A2 | c.937+14C>T | Intron (SNP) | VAF 22/154 reads (14%) | catalogued as rs1439806381; called by muse, mutect2, varscan2
- CASTOR2 | c.*3359C>T | 3'UTR (SNP) | VAF 8/180 reads (4%) | catalogued as rs982335242; called by muse, mutect2
- INKA1 | c.-21G>A | 5'UTR (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- PHF6 | c.834+63A>G | Intron (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792891 G>C | 3'Flank (SNP) | VAF 39/258 reads (15%) | called by muse, mutect2, varscan2
- RNU6-784P | chr4:70705258 ins GCG | 5'Flank (INS) | VAF 26/140 reads (19%) | catalogued as rs758130707; called by mutect2, varscan2
- RPL13AP20 | n.399A>C | RNA (SNP) | VAF 65/418 reads (16%) | called by muse, mutect2, varscan2
- SLC7A13 | c.1180-1001G>T | Intron (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- TCF3 | c.1823-409A>C | Intron (SNP) | VAF 19/77 reads (25%) | called by muse, varscan2
- TMEM169 | c.*11A>T | 3'UTR (SNP) | VAF 58/253 reads (23%) | called by muse, mutect2, varscan2
- XIAP | c.*4819T>C | 3'UTR (SNP) | VAF 56/318 reads (18%) | called by muse, mutect2, varscan2
